Surgical pathology report (de-identified scan), TCGA case TCGA-55-1594, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-1594-01A (Primary Tumor).

[page 1 of 3]
[Back to List](#)

REPORT STATUS: Final
FACILITY:
Patient:

Surgical Pathology SURGICAL P
SURGICAL PATHOLOGY REPORT

Billings

Specimen(s) Received

A: Right lower lobe
B: Level 3 sub carinal lymph node
C: Level 4 lymph node peritoneal

Pathologic Diagnosis

A. Right lower lobe:
Histologic Type: Adenocarcinoma
Histologic Grade: Poorly differentiated
Tumor Size: Greatest dimension: 3.7 cm
Additional dimension: 3.3 cm
Specimen Type: Lobectomy
Extent of Invasion: Tumor is confined to the lung
Regional Lymph Nodes: Number involved: 0
Number examined: 13
Distant Metastasis: Cannot be assessed
Margins: Margins uninvolved by invasive carcinoma
Tumor does not extend to pleural surface.
Tumor distance from pleural surface: 0.1cm.
Lymphovascular Invasion: Absent
Venous Invasion: Absent
Arterial Invasion: Absent

"A" - Lung, right lower lobe, lobectomy: Grade 3 adenocarcinoma (3.7 cm), subpleural in location, benign bronchial resection margin and 13 benign regional lymph nodes including 2 subpleural nodes and 2 nodes loose in the container.

"B" - Lymph nodes, level 7 subcarinal, biopsy: Metastatic poorly-differentiated carcinoma (0.7 cm) to one of nine lymph nodes (extranodal extension is not identified).

"C" - Lymph node, level 4, biopsy: Three benign lymph nodes.

PATHOLOGIC STAGE: pT2 pN2 pMX

NOTE: Information on pathology stage and the operative procedure

tal....

[page 2 of 3]
is transmitted to this Institution's Cancer Registry as required for accreditation by the [REDACTED] Pathology stage is based solely upon the current tissue specimen being evaluated and does not incorporate other relevant data. Pathology stage is only a component to be considered in determining the clinical stage and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

stage
[REDACTED]

).

Clinical History

Right posterior lung mass.

Intraoperative Consultation

A. Right lower lobe: Bronchial margin negative. (microscopic frozen section).

Gross Description

A: Received fresh for frozen section labeled "right lower lobe" is a 197 gram (post fixation weight), 15 x 12.5 x 4 cm lobe of lung. The bronchial margin is removed and frozen as "FS-A1". The frozen section remnant is submitted as "A1". Received with the lung are two separate lymph nodes, each 1.0 cm in greatest dimension. These detached lymph nodes are submitted intact as "A2". The pleura of the lung is tan-brown and focally retracted.

The retracted pleura is inked blue. Underlying the retracted pleura is a slightly soft white-gray 3.7 x 3.3 x 2.2 cm mass which comes to within approximately 4.5 cm of the bronchial margin. The remaining pleura demonstrates a moderate amount of anthracotic mottling. There are two potential subpleural lymph nodes identified between the mass and the bronchial margin. There are multiple lymph nodes identified near the bronchial margin within the parenchyma. Sectioning through the remaining specimen demonstrates soft tan-pink crepitus parenchyma with no additional masses or lesions identified. "A3 and A4" - mass with relationship to retracted pleura, "A5" - mass with relationship to adjacent parenchyma. "A6" - four potential intraparenchymal lymph nodes, "A7" - grossly unremarkable parenchyma greater than 2 cm from mass, "A8" - two intact potential subpleural lymph nodes, "A9 and A10" - vascular margins and intact potential lymph nodes and parenchyma surrounding bronchial vascular margins.

B: Received in formalin labeled "level 7 subcarinal lymph node" is a 3 x 3 x 1.5 cm aggregate of multiple matted gray-black lymph nodes with a small amount of attached adipose tissue.

"B1" - seven intact potential lymph nodes, "B2" - two bisected lymph nodes (one blue, one black).

C: Received in formalin labeled "level 4 paratracheal" is a 1.7 x 1.3 x 0.3 cm aggregate of gray-black lymph nodes and adipose tissue. The specimen is submitted intact in "C1".
[REDACTED]

Microscopic Description

Microscopic examination has been performed on all slides. The pathologic diagnosis encompasses the essential microscopic
[REDACTED]

Source: NCI Genomic Data Commons file 2dc465fb-947a-4703-9dd5-b91267f26627 (TCGA-55-1594.BDBFEF54-CA5A-4B4F-809D-4DE379232A8A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).